Somatic mutation profile of tumor specimen TARGET-30-PASRSG-01A (aliquot TARGET-30-PASRSG-01A-01D) from TARGET case TARGET-30-PASRSG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.7 years (1,361 days).
Specimen TARGET-30-PASRSG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d77064a9-b41a-4fc7-943a-b063978e8333.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASRSG-10A (Blood Derived Normal), aliquot TARGET-30-PASRSG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50a0aad8-75c6-42cd-82b2-8f660b84e402

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB5 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56674747; called by muse, mutect2, varscan2
- PTGDR | c.309G>C p.S103= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV100035386, COSV60095276; called by muse, mutect2, varscan2
- BSN | c.*706C>T | 3'UTR (SNP) | VAF 65/145 reads (45%) | catalogued as COSV56528803; called by muse, mutect2, varscan2
